Surgical pathology report (de-identified scan), TCGA case TCGA-DI-A1BU, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MD Anderson, specimen TCGA-DI-A1BU-01A (Primary Tumor).

[page 1 of 2]
Specimen Date/Time: (

100-0-3
Carcinoma, endometrioid, NOS 8380/3
Site Code: Endometrium C54.1

1/11
lw

DIAGNOSIS

- (A) UTERUS, CERVIX, BILATERAL FALLOPIAN TUBES AND OVARIES:
HIGH-GRADE ENDOMETRIAL ADENOCARCINOMA, MIXED SEROUS AND ENDOMETRIOID TYPE.
DEPTH OF MYOMETRIAL INVASION, 3.0 MM OUT OF 19 MM TOTAL MYOMETRIAL THICKNESS.
TUMOR INVADES 2.0 MM INTO THE 20 MM CERVIX.
LYMPHOVASCULAR INVASION IS PRESENT.
Leiomyoma.
Right and left ovaries, no tumor present.
Right and left fallopian tubes, paratubal cysts, no tumor present.
- (B) LEFT PELVIC LYMPH NODES:
Eleven lymph nodes, no tumor present (0/11).
- (C) RIGHT PELVIC LYMPH NODES:
Fourteen lymph nodes, no tumor present (0/14).
- (D) PORTION OF OMENTUM:
No tumor present.
- (E) RIGHT GONADAL VESSEL:
No tumor present.
- (F) PARAAORTIC LYMPH NODES:
Six lymph nodes, no tumor present (0/6).

GROSS DESCRIPTION

(A) UTERUS, CERVIX, BILATERAL FALLOPIAN TUBES AND OVARIES - A 13.5 x 8.5 x 6.0 cm uterus with a 4.4 x 4.0 cm cervix that has a smooth tan-white external surface. Attached is a left tube, 8.5 x 1.3 x 0.9 cm with a tubal ligation site within the central portion. Left ovary measures 2.6 x 1.3 x 1.2 cm and grossly unremarkable. Right fallopian tube measures 10.8 x 0.7 x 0.6 cm also with a central ligation site. The right ovary is 3.3 x 1.5 x 1.2 cm and has a 0.6 cm surface cyst. There are also multiple small paratubal cysts. The uterine serosal surface is pink, smooth tan and glistening.

The specimen is bivalved along the 3 and 9 o'clock positions to reveal a large exophytic, hemorrhagic tumor (12.5 x 8.3 x 2.4 cm) filling the uterine cavity. The tumor extends into the external cervical canal and comes to within 1.5 cm of the endo-ectocervix junction. The uterine wall adjacent to the most invasive portion of tumor is 2.8 cm in thickness.

In the anterior lateral wall is a 1.2 cm well circumscribed myometrial nodule grossly consistent with leiomyoma. Sectioning through the bilateral tubes and ovaries demonstrates a 0.6 cm cystic lesion within the left ovary. Sectioning through the left fallopian tube demonstrates hemorrhagic material within the lumen but no gross lesions present. Sectioning through the right ovary demonstrates the previously mentioned surface cyst 0.6 cm in greatest dimension filled with clear fluid. Sectioning through the right fallopian tube is grossly unremarkable.

INK CODE: Blue - anterior uterus; black - posterior uterus.

SECTION CODE: A1-A3, posterior cervix with tumor, one slice per cassette; A4, A5, anterior cervix with tumor; A6, A7, anterior cervix with tumor; A8-A14, sections of tumor from posterior with A9/10 full thickness; A15-A23, sections of tumor anterior wall with 18/19 full thickness; cassette 23 also myometrial nodule; A24, left tube, ovary and paratubal cyst; A25, right tube and ovary.

(B) LEFT PELVIC LYMPH NODES - Adipose tissue, 4.0 x 4.0 x 1.7 cm in aggregate. Multiple lymph nodes are identified ranging from 0.2 x 0.2 x 0.2 cm to 2.2 x 1.8 x 0.7 cm.

SECTION CODE: B1, four lymph nodes; B2, two lymph nodes; B3, two lymph nodes; B4, one lymph node serially sectioned; B5, one lymph node serially sectioned; B6, B7, one lymph node serially sectioned.

Reviewed Initials	RMT	lw

[page 2 of 2]
(C) RIGHT PELVIC LYMPH NODES - Multiple adipose tissues, 5.0 x 5.0 x 2.0 cm in aggregate. Multiple lymph nodes are identified ranging from 0.2 x 0.1 x 0.1 cm to 2.5 x 1.8 x 0.7 cm.

SECTION CODE: C1, four possible lymph nodes; C2, four lymph nodes; C3, three lymph nodes; C4, one lymph node trisected; C5, C6, one lymph node serially sectioned; C7, C8, one lymph node serially sectioned.

(D) PORTION OF OMENTUM - Received is a 57.0 x 15.5 x up to 2.0 cm sheet of finely lobulated adipose tissue. The specimen is serially sectioned to reveal cut surfaces composed of unremarkable yellow lobulated adipose tissue. A definite mass is not grossly identified.

SECTION CODE: D1-D7, representative sections.

(E) RIGHT GONADAL VESSEL - One portion of vascular structure, 6.5 x 0.3 x 0.3 cm and a round fibroadipose tissue. The specimen is serially sectioned. Cut surface reveal unremarkable vessel and soft tissue. Representative sections submitted in E.

(F) PARAAORTIC LYMPH NODES - Multiple adipose tissues, 4.0 x 4.0 x 1.8 cm in aggregate. Six lymph nodes are identified ranging from 0.4 x 0.4 x 0.4 cm to 2.5 x 1.5 x 1.0 cm.

SECTION CODE: F1, two lymph nodes; F2, two lymph nodes; F3, one lymph node serially sectioned; F4-F6, one lymph node serially sectioned.

CLINICAL HISTORY

Endometrial cancer.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Entire report and diagnosis completed by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 96f2ca57-84d3-4c5d-b749-06c56a10ff52 (TCGA-DI-A1BU.18A286FD-E85B-48FC-B193-456AB10D24B9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).